Somatic mutation profile of tumor specimen TCGA-KC-A4BL-01A (aliquot TCGA-KC-A4BL-01A-31D-A257-08) from TCGA case TCGA-KC-A4BL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.9 years (24,081 days).
Specimen TCGA-KC-A4BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 460175c6-4ad9-413e-81ba-d602b5cc4995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A4BL-10A (Blood Derived Normal), aliquot TCGA-KC-A4BL-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95c6a89f-c619-4715-95e7-eee364f209e0

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5267C>G p.P1756R | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV100250444; called by muse, mutect2
- CBX4 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV53965374, COSV99490222; called by muse, mutect2
- ERC1 | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.516); catalogued as COSV100705645; called by muse, mutect2, varscan2
- FUCA2 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 8/135 reads (6%) | catalogued as COSV99135985; called by muse, mutect2
- HSD17B4 | c.1285-2A>G p.X429_splice (on ENST00000414835 / NM_001199291.3; = p.X404_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/180 reads (6%) | catalogued as COSV99819542; called by muse, mutect2
- PRPF19 | c.658A>G p.S220G | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99920468; called by muse, mutect2
- RELA | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100425729; called by muse, mutect2
- TFDP1 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV100945735, COSV64739801; called by muse, mutect2
- DENND2A | c.1705G>C p.V569L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.255); called by muse, mutect2
- HOXA10 | c.491_495del p.K164Rfs*160 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- MECOM | c.2828C>A p.S943Y (on ENST00000468789 / NM_001105078.4; = p.S1131Y on NM_004991.4) | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- KRTAP9-2 | c.120C>T p.P40= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as rs527833476, COSV66646602; called by muse, mutect2
- NCL | c.1947T>C p.G649= | Silent (SNP) | VAF 42/511 reads (8%) | catalogued as rs763956578, COSV100502251; called by muse, mutect2
